Gene-level copy-number profile of tumor specimen TCGA-90-7769-01A from TCGA case TCGA-90-7769, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 55.5 years (20,276 days).
Specimen TCGA-90-7769-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.d18e69d5-6b51-413c-8247-c24a2e688e2e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-90-7769-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/13d74b3c-3670-4bc3-8cb1-ae85ba1257ab

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 3,753; copy number 2: 28,152; copy number 3: 18,509; copy number 4: 5,476; copy number 5: 2,264; copy number 6: 622; copy number 7: 648; copy number 8: 169; copy number 9: 189; copy number 10: 19; copy number 12: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-90-7769-01A-11D-2121-01): tumor purity 0.73, ploidy 2.61, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:16,473,038–16,617,058, 1 gene (within-gene range 0–4): RETREG1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,920 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:88,051,944–88,601,402, 9 genes, copy number 6 (within-gene range 3–6): CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5.
- chr3:89,588,714–104,063,582, 148 genes, copy number 7–12 (broad region; genes not listed).
- chr3:164,001,606–192,767,764, 461 genes, copy number 7–10 (broad region; genes not listed).
- chr4:43,972,921–45,326,028, 14 genes, copy number 5: AC114757.1, LINC02475, KCTD8, AC093852.1, YIPF7, GUF1, GNPDA2, AC096586.2, AC096586.1, AC093755.1, PRDX4P1, AC108467.2, AC108467.1, THAP12P9.
- chr5:2,261,859–13,250,662, 172 genes, copy number 5–6 (broad region; genes not listed).
- chr5:26,382,519–45,895,970, 294 genes, copy number 5 (broad region; genes not listed).
- chr6:49,714,325–49,820,503, 1 gene, copy number 7 (within-gene range 2–7): AL121974.1.
- chr6:49,785,660–56,394,094, 108 genes, copy number 5–10 (within-gene range 2–10) (broad region; genes not listed).
- chr7:75,533,298–143,027,195, 1,253 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:49,086,301–49,352,844, 3 genes, copy number 8–9: AC044893.1, RN7SKP294, RFPL4AP7.
- chr8:103,371,538–145,066,685, 612 genes, copy number 5–9 (broad region; genes not listed).
- chr15:25,456,271–32,186,475, 159 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr18:47,390–33,441,101, 582 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr19:27,638,483–32,691,750, 98 genes, copy number 7–9 (broad region; genes not listed).
- chr19:33,555,568–33,927,625, 6 genes, copy number 8: AC010485.1, RPL21P131, CHST8, KCTD15, AC008556.1, RN7SL150P.

Autosomal genes at a single copy (total copy number 1): 2,083. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
